Somatic mutation profile of tumor specimen TCGA-EL-A3CR-01A (aliquot TCGA-EL-A3CR-01A-12D-A202-08) from TCGA case TCGA-EL-A3CR, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 78.8 years (28,785 days).
Specimen TCGA-EL-A3CR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0120f0d-b9b0-4bf4-9cf6-054a73ab5d76.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3CR-10A (Blood Derived Normal), aliquot TCGA-EL-A3CR-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/903e2dc9-fac9-4081-90eb-9f8b4f036879

The open-access MAF lists 25 somatic variants for this specimen: 20 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 15, Silent 5, Nonsense Mutation 2, In Frame Del 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- PIK3CA | c.328_330del p.E110del | In Frame Del (DEL) | VAF 10/70 reads (14%) | hotspot (GDC flag); called by pindel, varscan2
- AJAP1 | c.1162C>T p.R388* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as COSV65452928; called by muse, mutect2
- CIDEA | c.392T>A p.F131Y | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV57599958; called by muse, mutect2, varscan2
- CPSF6 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV57016742; called by muse, mutect2, varscan2
- DMXL1 | c.6464T>G p.I2155S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60718529; called by muse, mutect2, varscan2
- DNAJC17 | c.211G>T p.A71S | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV55026040; called by muse, mutect2, varscan2
- FASTKD3 | c.172C>T p.H58Y | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs1208113081, COSV52945942; called by muse, mutect2, varscan2
- H2AW | c.119A>G p.Y40C | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.706); catalogued as rs1271494087, COSV64210062; called by muse, mutect2
- HAS1 | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs1416323528, COSV55789033; called by muse, mutect2, varscan2
- KRTAP4-12 | c.319C>G p.Q107E | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV67458159; called by muse, varscan2
- MMRN2 | c.452C>A p.P151H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV64401178; called by mutect2, varscan2
- OXR1 | c.1712T>C p.F571S (on ENST00000442977 / NM_001198532.1; = p.F570S on NM_018002.3) | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56334016; called by muse, mutect2, varscan2
- PCDHGA12 | c.1976C>G p.T659R | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.583); catalogued as COSV99341550; called by muse, mutect2, varscan2
- SIX5 | c.829G>C p.E277Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs756461023, COSV52180935; called by muse, mutect2, varscan2
- TBC1D2B | c.1354del p.E452Rfs*38 | Frame Shift Del (DEL) | VAF 6/53 reads (11%) | catalogued as COSV56040000; called by mutect2, pindel, varscan2
- TBL2 | c.1061T>G p.I354S | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs782679724, COSV59787885; called by muse, mutect2, varscan2
- TSPYL2 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs369549099; called by muse, mutect2
- UVSSA | c.842C>G p.S281* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as COSV66230603; called by muse, mutect2
- IGF1R | c.2765_2767del p.F922del | In Frame Del (DEL) | VAF 7/51 reads (14%) | called by pindel, varscan2
- CCM2L | c.111G>A p.R37= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as COSV52951865; called by muse, mutect2
- CHRM5 | c.873C>T p.S291= | Silent (SNP) | VAF 7/81 reads (9%) | catalogued as rs1368500477, COSV67246814, COSV67248720; called by muse, mutect2
- H2AC12 | c.57T>G p.S19= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as rs748519711, COSV100804766, COSV63617490; called by muse, mutect2, varscan2
- OR2D3 | c.435C>T p.P145= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as COSV53494305; called by muse, mutect2, varscan2
- PCDHA3 | c.510C>T p.Y170= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV100974087, COSV65369918; called by muse, mutect2
